Somatic mutation profile of tumor specimen TCGA-A7-A0CH-01A (aliquot TCGA-A7-A0CH-01A-21W-A019-09) from TCGA case TCGA-A7-A0CH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.7 years (29,104 days).
Specimen TCGA-A7-A0CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08fffdac-0553-4ff6-be0f-6f8aa3f79484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0CH-11A (Solid Tissue Normal), aliquot TCGA-A7-A0CH-11A-32W-A10F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23c0af0c-102c-40e6-8e93-7ec13bc032b9

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 42/77 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFTPH | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV53217321; called by muse, mutect2, varscan2
- AGO1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64595766; called by muse, mutect2
- ANGPTL1 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 31/537 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99328250; called by muse, mutect2
- C1QTNF2 | c.472G>C p.V158L (on ENST00000393975; = p.V113L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101220873; called by muse, mutect2
- C1orf198 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 61/272 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV64175142; called by muse, mutect2, varscan2
- CLNK | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV57013799, COSV99905754; called by muse, mutect2, varscan2
- DHX36 | c.2620G>A p.V874I | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as COSV57671959; called by muse, mutect2, varscan2
- DSC2 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs146754448, COSV51863677; called by muse, mutect2, varscan2
- FLG | c.7333C>A p.Q2445K | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100910483; called by muse, mutect2
- H2AC13 | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.939); catalogued as rs752581798, COSV62440707; called by muse, mutect2, varscan2
- KANK2 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62007526; called by muse, mutect2, varscan2
- PELO | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50880275; called by muse, mutect2, varscan2
- PGLYRP3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 14/492 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1426979746, COSV99319793; called by muse, mutect2
- PYM1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100212665; called by muse, mutect2
- RDH16 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV62458051; called by muse, mutect2
- SLCO3A1 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750983952, COSV59228656; called by muse, mutect2, varscan2
- ABCA1 | c.3395del p.K1132Rfs*21 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by mutect2, pindel, varscan2
- LMAN1 | c.1296_1301del p.T433_Q434del | In Frame Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, varscan2
- SOCS7 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPATA31A1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 47/930 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.236); called by muse, mutect2
- LSM1 | c.21C>T p.T7= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99781914; called by muse, mutect2
- MDGA1 | c.903G>A p.R301= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1453838278, COSV51794758; called by muse, mutect2, varscan2
- STT3A | c.762C>T p.I254= | Silent (SNP) | VAF 10/282 reads (4%) | catalogued as COSV101205218; called by muse, mutect2
- TTN | c.16416C>T p.L5472= (on ENST00000591111; = p.L4545= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/379 reads (6%) | catalogued as COSV100619173; called by muse, mutect2
- VN1R5 | c.426C>T p.L142= | Silent (SNP) | VAF 34/466 reads (7%) | called by muse, mutect2
- ZFHX4 | c.8499G>A p.V2833= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV99264502; called by muse, mutect2
